Surgical pathology report (de-identified scan), TCGA case TCGA-56-A4BY, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A4BY-01A (Primary Tumor).

[page 1 of 2]
Sex: Male
D.O.B.:
MRN #:
Ref Phys.:

SPECIMEN IN

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Lymph node, labeled left upper lobe level 12, biopsy:
Single lymph node negative for malignancy (0/1).

B. Left lung, upper lobe, lobectomy:

Tumor Characteristics:

1. Histologic type: Focally keratinizing squamous carcinoma.
2. Histologic grade: Moderately differentiated.
3. Tumor site: Left upper lobe.
4. Tumor focality: Unifocal.
5. Tumor size: 4.8 x 2.0 x 2.0 cm.
6. Visceral pleural invasion: No.
7. Lymphovascular space invasion: No.
8. Tumor extension: Confined to the lung.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 3.5 cm.
2. Tumor distance from pleural surface: Tumor abuts the pleural.

Other:

1. pTNM stage: T2N0.

C. Lymph node, labeled level V/level VI, biopsy:
Single lymph node, negative for malignancy.

D. Lymph node, level VII, biopsy:
Single lymph node negative for malignancy.

ICD-O-3
carcinoma, squamous cell, Keratinizing, no:
(L) 8071/3
Site: lung, upper lobe C34.1

hw
9/26/12

Electronic Signature:

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: y/o male, lung mass

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Left upper lobe level 12
- B. Left upper lobe
- C. Level 5/level 6
- D. Level 7

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in four containers labeled with the patient's name

A. Container A is additionally labeled 'left upper lobe level 12' and contains multiple rubbery black nodules consistent with anthracotic lymph nodes. The nodules aggregate to 3.3 x 3.0 x 1.4 cm. They are entirely submitted in cassettes A1 and 2 labeled

B. Container B is additionally labeled 'left upper lobe' and contains a 19.0 x 8.5 x 6.0 cm lung lobe bearing a 1.0 cm in length x 2.0 cm in diameter

[page 2 of 2]
segment of exposed bronchus. Adjacent to the bronchus are segments of stapled and sutured vasculature. Bronchus is lined by pink-tan endothelium with no discrete lesions. Located 1.5 cm from the bronchial margin is a 3.5 cm in length stapled parenchymal margin. The staple line is removed and the underlying parenchyma is inked black. The pleura is purple-gray and diffusely anthracotic. Sectioning reveals 4.8 x 2.0 x 2.0 cm ill-defined yellow-tan mass that resides 3.5 cm from the bronchial margin and 3.0 cm from the nearest vascular margin. This mass abuts and umbilicates the pleura, which is now inked black. Additionally, this mass approaches to within 2.5 cm of the stapled parenchymal margin. The remainder of the cut surface features marked emphysematous change with red-brown and clotted blood. Additional masses are not identified. Discrete parabronchial lymph nodes are not identified. Representative sections are submitted in cassettes B1 through 10 labeled as follows: 1 and 2, bronchial and vascular margins, en face; 3, intraparenchymal margin, perpendicular; 4 through 8, mass to inked pleura, perpendicular; 9 and 10, additional representative sections to include emphysematous change. Additionally, a yellow and green cassette are submitted for genomics research each labeled

C. Container C is additionally labeled 'level 5/level 6' and contains a 0.4 cm gray-black rubbery nodule consistent with anthracotic lymph node, entirely submitted in cassette C labeled

D. Container D is additionally labeled 'level 7' and contains a 0.9 cm yellow-gray to black firm rubbery nodule consistent with lymph node. The nodule is entirely submitted in cassette D1 labeled

MICROSCOPIC EXAMINATION:

Microscopic examination demonstrates a squamous carcinoma. The tumor approaches, but does not penetrate the pleural surface. Sections of the tumor where it is closest to the pleural surface are examined following an elastic stain. Diagnostic evidence of encroachment of the elastic tissue is not identified in this section. Pleural invasion is therefore not seen.

Prior Incidental History		X

8/24/13

Source: NCI Genomic Data Commons file 9e8ab55e-0549-4994-9b39-24ad6a0b6762 (TCGA-56-A4BY.62DC00DE-B06C-4A85-A1DB-3B6498D617C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).